Somatic mutation profile of tumor specimen ALCH-B2BR-TTP1-A (aliquot ALCH-B2BR-TTP1-A-2-0-D-A776-36) from ALCHEMIST case ALCH-B2BR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.2 years (23,071 days).
Specimen ALCH-B2BR-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2acb914-dee6-4e2a-8ecc-3128717ea3d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2BR-NB1-A (Blood Derived Normal), aliquot ALCH-B2BR-NB1-A-1-0-D-A776-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c7b9644-6a26-4581-9786-7412c594cea0

The open-access MAF lists 302 somatic variants for this specimen: 196 protein-altering or splice-affecting, 61 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 167, Silent 61, Intron 25, Nonsense Mutation 14, Splice Site 8, RNA 6, 5'UTR 5, Splice Region 5, 3'UTR 5, 5'Flank 2, Frame Shift Ins 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS16 | c.2459G>A p.R820Q | Missense Mutation (SNP) | VAF 39/481 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748937514, COSV56992018, COSV99941221; called by muse, mutect2
- ADH6 | c.754C>G p.Q252E | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV52956965; called by muse, mutect2
- ALMS1 | c.10828A>T p.R3610W | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as CD075308; called by muse, mutect2, varscan2
- ANKS4B | c.944C>A p.A315E | Missense Mutation (SNP) | VAF 22/427 reads (5%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV61139519; called by muse, mutect2
- ARHGEF4 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 28/454 reads (6%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.001); catalogued as rs1360082869; called by muse, mutect2
- ARID1A | c.6109C>T p.Q2037* | Nonsense Mutation (SNP) | VAF 19/310 reads (6%) | catalogued as COSV61372657; called by muse, mutect2
- ARID1B | c.3723G>A p.M1241I | Missense Mutation (SNP) | VAF 26/281 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV51663679; called by muse, mutect2
- BEND3 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV100944537; called by muse, mutect2, varscan2
- BOC | c.2257C>G p.R753G | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56350935; called by muse, mutect2
- BTBD19 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV69768309; called by muse, mutect2
- CD5 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776820706, COSV61718975; called by muse, mutect2
- CDRT1 | c.1729G>A p.V577M | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1179082047, COSV63052592; called by muse, mutect2
- CFH | c.620-1G>C p.X207_splice | Splice Site (SNP) | VAF 8/132 reads (6%) | catalogued as COSV62777152; called by muse, mutect2
- CHD7 | c.8405G>C p.G2802A | Missense Mutation (SNP) | VAF 23/279 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as CM1413038, COSV101418669; called by muse, mutect2
- CHST3 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64151574; called by muse, mutect2
- CLUL1 | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 28/350 reads (8%) | catalogued as rs1567976664; called by muse, mutect2
- CNOT3 | c.387G>A p.T129= | Splice Region (SNP) | VAF 4/32 reads (13%) | catalogued as COSV55361055; called by muse, mutect2, varscan2
- COL8A1 | c.1220T>C p.I407T | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs768208846; called by muse, mutect2
- CYP11B2 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 75/445 reads (17%) | catalogued as COSV59998336; called by muse, mutect2, varscan2
- DCC | c.136C>A p.P46T | Missense Mutation (SNP) | VAF 29/323 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59096341; called by muse, mutect2
- DICER1 | c.4991C>T p.S1664L | Missense Mutation (SNP) | VAF 40/375 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs988095775, COSV58621482; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLGAP2 | c.2027C>A p.A676E | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776882325; called by muse, mutect2, varscan2
- DMXL2 | c.4655G>C p.R1552T | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs763012785, COSV99198046; called by muse, mutect2
- DRD1 | c.67C>G p.R23G | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs757759969, COSV67104946; called by muse, mutect2
- DSP | c.6187C>G p.R2063G | Missense Mutation (SNP) | VAF 23/286 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as rs374090050, COSV101131684; ClinVar: uncertain significance; called by muse, mutect2
- ECM1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as rs1474836432, COSV60871859; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1669G>T p.A557S (on ENST00000361735 / NM_015935.5; = p.A471S on NM_014955.3) | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs772705665; called by muse, mutect2, varscan2
- FCN2 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.286); catalogued as COSV52476007, COSV99391375; called by muse, mutect2
- FLG | c.7598G>A p.R2533H | Missense Mutation (SNP) | VAF 40/464 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs754603159, COSV64239282; called by muse, mutect2
- GPR171 | c.462C>G p.I154M | Missense Mutation (SNP) | VAF 38/642 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV56389024; called by muse, mutect2
- HCN1 | c.2488G>A p.G830R | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.621); catalogued as rs1484753978, COSV57504841, COSV57520133; called by muse, mutect2
- HOXC5 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV54536368; called by muse, mutect2
- IL1RAPL2 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV61143544, COSV61155825; called by muse, mutect2, varscan2
- INA | c.944A>T p.Y315F | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as COSV63975750; called by muse, mutect2
- KIF4A | c.2504C>T p.A835V | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100979445; called by muse, mutect2, varscan2
- KRT77 | c.1271C>G p.A424G | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59239659; called by muse, mutect2
- KRTAP19-7 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.766); catalogued as COSV58366641; called by muse, mutect2, varscan2
- LCT | c.2260G>T p.G754W | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51546182; called by muse, mutect2
- LZTR1 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.325); catalogued as CM151191, COSV53152095, COSV99302575; called by muse, mutect2, varscan2
- MAGEC1 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as COSV99596225; called by muse, varscan2
- MCAM | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as rs748225145; called by muse, mutect2, varscan2
- METTL14 | c.1046G>C p.R349T | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as COSV66310824; called by muse, mutect2
- MMP17 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770270565; called by muse, mutect2, varscan2
- MYH11 | c.769G>A p.V257M | Missense Mutation (SNP) | VAF 34/578 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as rs112992497, COSV55557421; ClinVar: uncertain significance; called by muse, mutect2
- MYRIP | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.665); catalogued as rs1229944003, COSV56864186; called by muse, mutect2
- NCKAP5 | c.5675G>C p.R1892T | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.544); catalogued as COSV58471279; called by muse, mutect2
- OR2T33 | c.256G>T p.G86* | Nonsense Mutation (SNP) | VAF 66/944 reads (7%) | catalogued as COSV100532243; called by muse, mutect2
- OR8K5 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV100537295, COSV57888322, COSV57890208; called by muse, mutect2
- PAH | c.1132A>G p.T378A | Missense Mutation (SNP) | VAF 29/472 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as CM002086; called by muse, mutect2
- PCDH10 | c.1759C>G p.R587G | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.129); catalogued as COSV52088168, COSV52103034; called by muse, mutect2
- PCSK2 | c.188C>G p.A63G | Missense Mutation (SNP) | VAF 18/227 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV104391066; called by muse, mutect2
- PDE11A | c.1867A>G p.M623V | Missense Mutation (SNP) | VAF 40/555 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1471297033; called by muse, mutect2
- PLCB1 | c.2251G>T p.E751* | Nonsense Mutation (SNP) | VAF 22/247 reads (9%) | catalogued as COSV62060368; called by muse, mutect2
- PNISR | c.2217T>A p.D739E | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV65080035; called by muse, mutect2, varscan2
- PNLIP | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 26/464 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1349991608; called by muse, mutect2
- POT1 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs797045168, CM1412277, COSV62928287; ClinVar: risk factor / uncertain significance; called by muse, varscan2
- PUS10 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 34/481 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57452674; called by muse, mutect2
- SAMD9L | c.3425G>T p.R1142M | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.35); catalogued as COSV100560558; called by muse, mutect2
- SLC27A5 | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148336155, COSV99564212; called by muse, mutect2, varscan2
- SLC2A2 | c.291G>T p.W97C | Missense Mutation (SNP) | VAF 34/341 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1407375423; called by muse, mutect2
- SLC2A7 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | catalogued as COSV68901831; called by muse, mutect2, varscan2
- SPEF2 | c.5256G>T p.E1752D | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57427554; called by muse, mutect2
- SSC5D | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs1423657681; called by muse, mutect2, varscan2
- STAT5B | c.1648G>A p.G550S | Missense Mutation (SNP) | VAF 55/552 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV53181147; called by muse, mutect2
- TAS2R50 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67862694; called by muse, mutect2
- TDRD15 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs915224216; called by muse, mutect2
- TEKT4 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 26/281 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.269); catalogued as rs1553395883; called by muse, mutect2
- TYMS | c.722C>A p.T241K | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV51893737; called by muse, mutect2
- ZC3H4 | c.1882A>T p.M628L | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs374529527; called by muse, mutect2, varscan2
- ZKSCAN8 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332150130; called by muse, mutect2, varscan2
- ZNF365 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 27/343 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753296335, COSV101237928; called by muse, mutect2
- ZNF366 | c.2066A>T p.Q689L | Missense Mutation (SNP) | VAF 38/506 reads (8%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100574607; called by muse, mutect2
- ZSWIM6 | c.2746G>T p.E916* | Nonsense Mutation (SNP) | VAF 8/163 reads (5%) | catalogued as COSV53174811; called by muse, mutect2
- AAK1 | c.398A>T p.Q133L | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- ABCC5 | c.209G>A p.R70K | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); called by muse, mutect2
- ACAP2 | c.1973A>T p.E658V | Missense Mutation (SNP) | VAF 24/321 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACTN2 | c.820G>T p.A274S | Missense Mutation (SNP) | VAF 29/398 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.028); called by muse, mutect2
- ADAMTS12 | c.3301C>A p.P1101T | Missense Mutation (SNP) | VAF 29/296 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY2 | c.1466G>T p.R489M | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2
- ALK | c.2198C>A p.T733N | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.718); called by muse, mutect2
- ALMS1 | c.11548-1G>T p.X3850_splice | Splice Site (SNP) | VAF 14/291 reads (5%) | called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.3578C>T p.P1193L | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANXA11 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 23/328 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.795); called by muse, mutect2
- C12orf42 | c.370T>C p.Y124H | Missense Mutation (SNP) | VAF 42/454 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- C4orf19 | c.476G>C p.R159T | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CACNA1C | c.6529G>C p.D2177H (on ENST00000399634 / NM_001167625.1; = p.D2106H on NM_000719.7) | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); called by muse, mutect2
- CCDC61 | c.231+6G>C | Splice Region (SNP) | VAF 18/93 reads (19%) | called by muse, mutect2, varscan2
- CCNQ | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CD6 | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- CD96 | c.488G>A p.C163Y | Missense Mutation (SNP) | VAF 23/378 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- CDH23 | c.4469T>A p.L1490Q | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CEP83 | c.934-1G>T p.X312_splice | Splice Site (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- CFAP44 | c.3877G>T p.G1293* | Nonsense Mutation (SNP) | VAF 25/258 reads (10%) | called by muse, mutect2
- CLOCK | c.1206+2dup | Splice Region (INS) | VAF 24/224 reads (11%) | called by mutect2, varscan2
- CMIP | c.452A>T p.Q151L (on ENST00000537098 / NM_198390.2; = p.Q57L on NM_030629.3) | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2
- CPA2 | c.845C>A p.S282Y | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRACD | c.900G>T p.W300C | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- DLST | c.1304dup p.L436Pfs*47 | Frame Shift Ins (INS) | VAF 10/108 reads (9%) | called by mutect2, pindel
- DNAJB5 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); called by muse, mutect2
- DOCK7 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 14/258 reads (5%) | called by muse, mutect2
- DOP1B | c.1882C>G p.L628V | Missense Mutation (SNP) | VAF 24/289 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.021); called by muse, mutect2
- DTNA | c.2082-1G>C p.X694_splice | Splice Site (SNP) | VAF 30/459 reads (7%) | called by muse, mutect2
- EARS2 | c.1028C>G p.S343* | Nonsense Mutation (SNP) | VAF 20/208 reads (10%) | called by muse, mutect2
- EFCAB10 | c.32C>A p.A11E | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.045); called by muse, mutect2
- ELOVL4 | c.461T>G p.V154G | Missense Mutation (SNP) | VAF 33/353 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ENTPD4 | c.220G>T p.V74F | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2
- EPHA6 | c.2534T>A p.V845E (on ENST00000389672 / NM_001080448.3; = p.V237E on NM_173655.4) | Missense Mutation (SNP) | VAF 26/313 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ERAP1 | c.136C>G p.P46A | Missense Mutation (SNP) | VAF 37/525 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.04); called by muse, mutect2
- ESX1 | c.637C>A p.H213N | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- EXOC7 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 17/286 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2
- FAM83H | c.3254C>T p.S1085F | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- FBXW4 | c.923G>C p.R308P | Missense Mutation (SNP) | VAF 26/508 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2
- FDXR | c.1003-7C>G | Splice Region (SNP) | VAF 15/171 reads (9%) | called by muse, mutect2
- FGD5 | c.3356C>A p.T1119K | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FST | c.750C>A p.C250* | Nonsense Mutation (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- GABRG2 | c.108C>A p.G36= | Splice Region (SNP) | VAF 22/446 reads (5%) | called by muse, mutect2
- GAP43 | c.278C>G p.A93G | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- GDPD4 | c.1211A>T p.D404V | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- HDAC8 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- HDGFL1 | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by mutect2, varscan2
- HRC | c.1558G>T p.E520* | Nonsense Mutation (SNP) | VAF 47/194 reads (24%) | called by muse, mutect2, varscan2
- HSPA9 | c.1904A>G p.Q635R | Missense Mutation (SNP) | VAF 52/612 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by muse, mutect2
- IFFO2 | c.1485C>G p.D495E | Missense Mutation (SNP) | VAF 20/339 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.967); called by muse, mutect2
- IPP | c.1310G>A p.G437D | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.71); called by muse, mutect2
- KCNA10 | c.1010T>A p.L337Q | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- KIR2DL4 | c.298delinsCT p.T100Lfs*12 (on ENST00000396284; = p.T61Lfs*12 on NM_001080770.2) | Frame Shift Ins (INS) | VAF 30/279 reads (11%) | called by pindel, varscan2*
- KLHL24 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.065); called by muse, mutect2
- LHX9 | c.8T>C p.I3T | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by muse, mutect2
- LRRC28 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- MAGI2 | c.3206A>T p.Y1069F | Missense Mutation (SNP) | VAF 20/472 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.185); called by muse, mutect2
- MED12L | c.3223-1G>T p.X1075_splice | Splice Site (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- MEIS1 | c.555G>T p.L185F | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); called by muse, mutect2
- MNDA | c.86T>A p.L29Q | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MRPS5 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 20/217 reads (9%) | called by muse, mutect2
- MYO1D | c.1782C>G p.D594E | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2
- MYOM2 | c.1185C>A p.N395K | Missense Mutation (SNP) | VAF 13/261 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2
- NBEAL1 | c.204G>T p.R68S | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.29); called by muse, mutect2
- NCKAP1 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NEBL | c.2493G>A p.M831I | Missense Mutation (SNP) | VAF 52/560 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2
- NLRP3 | c.1106T>A p.L369Q | Missense Mutation (SNP) | VAF 38/358 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NRK | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- NT5DC4 | c.1093C>A p.L365M | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2
- NUDC | c.51G>C p.M17I | Missense Mutation (SNP) | VAF 41/391 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- OR4Q2 | c.716C>A p.A239D | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- OR5T1 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OTOGL | c.1123C>A p.P375T (on ENST00000547103; = p.P366T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OTOGL | c.1124C>G p.P375R (on ENST00000547103; = p.P366R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/419 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PASK | c.2708G>A p.G903D | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PATL1 | c.1103G>A p.R368K | Missense Mutation (SNP) | VAF 26/361 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- PCK1 | c.1725G>A p.M575I | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- PHRF1 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2
- PIGG | c.1598G>A p.G533E (on ENST00000453061 / NM_001127178.3; = p.G525E on NM_017733.4) | Missense Mutation (SNP) | VAF 45/397 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PITPNM1 | c.2203C>T p.P735S | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLXNB3 | c.2474C>G p.P825R | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PTCH1 | c.3308C>A p.A1103D | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- RAD54L2 | c.4322C>G p.S1441C | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.156); called by muse, mutect2
- SDSL | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); called by muse, mutect2
- SEMG2 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2
- SLC12A3 | c.11T>A p.L4Q | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLC32A1 | c.581G>A p.C194Y | Missense Mutation (SNP) | VAF 20/207 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SLC44A1 | c.1494G>T p.Q498H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); called by muse, mutect2
- SLF2 | c.3082G>A p.E1028K | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.198); called by muse, mutect2
- SOX17 | c.587C>A p.P196H | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2
- SPATA4 | c.218+1_218+13del p.X73_splice | Splice Site (DEL) | VAF 12/146 reads (8%) | called by mutect2, pindel
- SRP68 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- SSRP1 | c.802A>T p.T268S | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STARD6 | c.111T>G p.S37R | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.188); called by muse, mutect2
- STOML3 | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.058); called by muse, mutect2
- SULT1A1 | c.323A>G p.H108R | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TARM1 | c.326G>T p.R109I (on ENST00000616041 / NM_001330650.1; = p.R101I on NM_001135686.3) | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- TCF20 | c.3590C>A p.P1197Q | Missense Mutation (SNP) | VAF 29/349 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TEPSIN | c.94C>G p.P32A | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TIAM1 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TMTC3 | c.2549G>C p.R850T | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNS1 | c.4121C>G p.S1374C | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- TRHDE | c.1054-2A>G p.X352_splice | Splice Site (SNP) | VAF 12/139 reads (9%) | called by muse, mutect2
- TRIO | c.3104A>T p.K1035M | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TUBGCP5 | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2
- UBXN2B | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 13/209 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- UNC80 | c.4079T>C p.F1360S | Missense Mutation (SNP) | VAF 32/440 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- VPS13D | c.3493G>T p.E1165* | Nonsense Mutation (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- WDR76 | c.1096C>G p.L366V | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.842); called by muse, mutect2
- WDR81 | c.2601C>G p.F867L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by mutect2, varscan2
- ZBTB47 | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZFHX4 | c.10171T>A p.S3391T | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.21); called by muse, mutect2
- ZIM3 | c.164C>G p.P55R | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- ZNF131 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); called by muse, mutect2
- ZNF479 | c.1340G>T p.S447I | Missense Mutation (SNP) | VAF 28/419 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.693); called by muse, mutect2
- ZNF501 | c.701G>T p.S234I | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.048); called by muse, mutect2
- ZNF521 | c.359G>T p.C120F | Missense Mutation (SNP) | VAF 29/432 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF687 | c.209C>G p.S70C | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF827 | c.3032G>T p.S1011I | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF836 | c.2132G>T p.R711I | Missense Mutation (SNP) | VAF 55/393 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZNF875 | c.1746G>T p.R582S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZYG11A | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZYG11B | c.1695+2T>G p.X565_splice | Splice Site (SNP) | VAF 11/162 reads (7%) | called by muse, mutect2
- ABI1 | c.57G>C p.L19= | Silent (SNP) | VAF 36/568 reads (6%) | called by muse, mutect2
- ADAMTSL3 | c.2619A>G p.R873= | Silent (SNP) | VAF 22/285 reads (8%) | called by muse, mutect2
- ADGRV1 | c.16932C>G p.L5644= | Silent (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- ANKRD35 | c.2406G>T p.G802= | Silent (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- ASTN2 | c.2691C>T p.I897= (on ENST00000313400 / NM_001365069.1; = p.I846= on NM_014010.5) | Silent (SNP) | VAF 24/317 reads (8%) | catalogued as rs1462611954, COSV57817695; called by muse, mutect2
- BTBD8 | c.2661C>T p.D887= (on ENST00000636805 / NM_001376131.1; = p.D374= on NM_015237.4) | Silent (SNP) | VAF 17/159 reads (11%) | called by muse, mutect2, varscan2
- CASS4 | c.1530T>C p.S510= | Silent (SNP) | VAF 15/129 reads (12%) | called by muse, mutect2, varscan2
- CFAP91 | c.1992G>A p.R664= | Silent (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- CTNNA1 | c.1425A>T p.P475= | Silent (SNP) | VAF 16/167 reads (10%) | called by muse, mutect2, varscan2
- CUX2 | c.148C>A p.R50= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as COSV55630862; called by muse, mutect2
- DCAF8L2 | c.1188G>A p.Q396= | Silent (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2, varscan2
- DNAH7 | c.9786T>C p.F3262= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs1392384226; called by muse, mutect2
- ERP29 | c.435G>A p.L145= | Silent (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- ESX1 | c.636C>A p.A212= | Silent (SNP) | VAF 29/140 reads (21%) | catalogued as COSV101006488; called by muse, mutect2, varscan2
- EYA4 | c.306C>T p.P102= | Silent (SNP) | VAF 32/395 reads (8%) | catalogued as COSV62046347; called by muse, mutect2
- FAM205A | c.1719C>T p.S573= | Silent (SNP) | VAF 21/334 reads (6%) | called by muse, mutect2
- FLNC | c.6810G>A p.E2270= | Silent (SNP) | VAF 26/282 reads (9%) | catalogued as rs745858001; ClinVar: likely benign; called by muse, mutect2
- GEMIN5 | c.435G>A p.Q145= | Silent (SNP) | VAF 34/340 reads (10%) | catalogued as COSV53563555; called by muse, mutect2
- GLIS3 | c.15A>G p.S5= | Silent (SNP) | VAF 33/333 reads (10%) | called by muse, mutect2, varscan2
- GPR174 | c.870C>A p.V290= | Silent (SNP) | VAF 20/116 reads (17%) | called by muse, mutect2, varscan2
- GSPT2 | c.144C>T p.F48= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV100468454; called by muse, mutect2
- H3-3B | c.300C>T p.Y100= | Silent (SNP) | VAF 20/237 reads (8%) | catalogued as rs139372371; called by muse, mutect2
- HECTD4 | c.10014G>C p.V3338= | Silent (SNP) | VAF 19/205 reads (9%) | called by muse, mutect2
- HTR3D | c.174C>T p.N58= | Silent (SNP) | VAF 26/235 reads (11%) | called by muse, mutect2, varscan2
- KCNQ2 | c.2004G>A p.P668= (on ENST00000359125 / NM_172107.4; = p.P640= on NM_004518.6) | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs771807099, COSV100610430; called by muse, mutect2, varscan2
- LRRIQ1 | c.2046T>C p.A682= | Silent (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- MAD1L1 | c.1128C>T p.V376= | Silent (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- MAN2B2 | c.1854G>A p.L618= | Silent (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- MDN1 | c.9960G>T p.L3320= | Silent (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- MKRN3 | c.840C>A p.A280= | Silent (SNP) | VAF 23/295 reads (8%) | called by muse, mutect2
- MMACHC | c.837C>T p.S279= | Silent (SNP) | VAF 24/338 reads (7%) | called by muse, mutect2
- MORN5 | c.414T>C p.Y138= | Silent (SNP) | VAF 33/427 reads (8%) | called by muse, mutect2
- MSANTD2 | c.150C>G p.L50= | Silent (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- MSH4 | c.57G>T p.S19= | Silent (SNP) | VAF 32/359 reads (9%) | called by muse, mutect2
- MUC12 | c.13182A>C p.P4394= (on ENST00000379442; = p.P4251= on NM_001164462.1) | Silent (SNP) | VAF 36/658 reads (5%) | catalogued as rs1368916711; called by muse, mutect2
- MUC16 | c.38661G>T p.L12887= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV67496450; called by muse, mutect2
- NLRX1 | c.1647G>T p.L549= | Silent (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- NPR3 | c.433C>A p.R145= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as COSV54090314; called by muse, mutect2, varscan2
- NPY2R | c.480C>T p.I160= | Silent (SNP) | VAF 6/111 reads (5%) | catalogued as COSV61528921; called by muse, mutect2
- NRAP | c.3858G>T p.L1286= (on ENST00000359988 / NM_001322945.2; = p.L1251= on NM_006175.4) | Silent (SNP) | VAF 36/449 reads (8%) | catalogued as COSV63492422; called by muse, mutect2
- NWD2 | c.3964C>T p.L1322= | Silent (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- OR2M2 | c.258G>C p.L86= | Silent (SNP) | VAF 37/418 reads (9%) | catalogued as COSV100677141; called by muse, mutect2
- OR4K14 | c.840T>A p.T280= | Silent (SNP) | VAF 21/249 reads (8%) | called by muse, mutect2
- PCDHGB2 | c.1533C>T p.S511= | Silent (SNP) | VAF 25/435 reads (6%) | catalogued as rs923388451, COSV53916871; called by muse, mutect2
- PEG3 | c.3183G>A p.E1061= | Silent (SNP) | VAF 21/105 reads (20%) | called by muse, mutect2, varscan2
- PLAUR | c.12G>T p.P4= | Silent (SNP) | VAF 37/228 reads (16%) | called by muse, mutect2, varscan2
- POSTN | c.1623T>C p.F541= | Silent (SNP) | VAF 12/198 reads (6%) | called by muse, mutect2
- PTPRR | c.1149G>C p.L383= | Silent (SNP) | VAF 30/299 reads (10%) | called by muse, mutect2, varscan2
- SELENOF | c.36G>T p.L12= | Silent (SNP) | VAF 40/491 reads (8%) | called by muse, mutect2
- SH3TC2 | c.3285C>T p.F1095= | Silent (SNP) | VAF 42/638 reads (7%) | called by muse, mutect2
- SV2A | c.1752G>T p.P584= | Silent (SNP) | VAF 42/450 reads (9%) | called by muse, mutect2
- TADA3 | c.876T>G p.A292= | Silent (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- TRPM6 | c.4036C>T p.L1346= | Silent (SNP) | VAF 36/524 reads (7%) | catalogued as rs771456641; called by muse, mutect2
- TWIST1 | c.591C>A p.S197= | Silent (SNP) | VAF 13/150 reads (9%) | called by muse, mutect2
- TXN2 | c.411G>T p.L137= | Silent (SNP) | VAF 20/294 reads (7%) | called by muse, mutect2
- UNG | c.897G>T p.L299= (on ENST00000242576 / NM_080911.3; = p.L290= on NM_003362.4) | Silent (SNP) | VAF 42/462 reads (9%) | called by muse, mutect2
- WDR62 | c.246A>G p.T82= | Silent (SNP) | VAF 67/415 reads (16%) | called by muse, mutect2, varscan2
- WSCD2 | c.1236C>T p.D412= | Silent (SNP) | VAF 28/364 reads (8%) | catalogued as rs760395169, COSV54584112; called by muse, mutect2
- ZNF260 | c.855C>T p.F285= | Silent (SNP) | VAF 14/385 reads (4%) | called by muse, mutect2
- ZNF324B | c.1032C>T p.S344= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs755008243, COSV60743380; called by mutect2, varscan2
- ZNF528 | c.1614A>G p.R538= | Silent (SNP) | VAF 26/220 reads (12%) | catalogued as rs758320180; called by muse, mutect2, varscan2
- AC018521.7 | n.329G>T | RNA (SNP) | VAF 16/152 reads (11%) | called by muse, mutect2, varscan2
- AC024940.1 | n.4510C>A | RNA (SNP) | VAF 10/145 reads (7%) | catalogued as rs1188026170; called by muse, mutect2
- AL136982.4 | n.924C>T | RNA (SNP) | VAF 50/482 reads (10%) | catalogued as rs374494942; called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+38858C>G | Intron (SNP) | VAF 18/268 reads (7%) | called by muse, mutect2
- CCDC105 | chr19:15010535 del TAAAGCTGGAAGAAGGGCCATGTTGCTGGAAGCAACGGCGAGAAGGATGCT | 5'Flank (DEL) | VAF 10/89 reads (11%) | called by mutect2, pindel
- CD59 | c.68-46A>T | Intron (SNP) | VAF 25/300 reads (8%) | called by muse, mutect2
- CD8B | c.-1G>A | 5'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
- CORO1A | c.756+23G>A | Intron (SNP) | VAF 18/172 reads (10%) | catalogued as rs556055190; called by muse, mutect2, varscan2
- CPS1 | c.3667-31G>T | Intron (SNP) | VAF 25/351 reads (7%) | called by muse, mutect2
- CTNNA2 | c.102+35968C>A | Intron (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2
- DDB2 | c.881-11C>T | Intron (SNP) | VAF 48/528 reads (9%) | called by muse, mutect2
- DTNA | c.1662+2120C>A | Intron (SNP) | VAF 20/294 reads (7%) | called by muse, mutect2
- DYNC2LI1 | c.321-1764C>T | Intron (SNP) | VAF 16/153 reads (10%) | called by muse, mutect2, varscan2
- EIF4G2 | c.1413+101G>C | Intron (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2, varscan2
- FAM182A | n.923C>A | RNA (SNP) | VAF 16/140 reads (11%) | called by muse, varscan2
- FAM74A3 | n.125C>A | RNA (SNP) | VAF 50/818 reads (6%) | called by muse, mutect2
- FAM83H | c.*6C>G | 3'UTR (SNP) | VAF 33/189 reads (17%) | called by muse, mutect2, varscan2
- FDXR | c.177+2041C>T | Intron (SNP) | VAF 8/107 reads (7%) | called by muse, mutect2
- GK5 | c.411+37T>G | Intron (SNP) | VAF 11/132 reads (8%) | called by muse, mutect2
- IGLL5 | c.-38G>A | 5'UTR (SNP) | VAF 34/350 reads (10%) | catalogued as rs558520048, COSV73249446; called by muse, mutect2
- KCNMA1 | c.3017-20T>C | Intron (SNP) | VAF 26/379 reads (7%) | catalogued as COSV99700833; called by muse, mutect2
- LINC02656 | n.300C>G | RNA (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2, varscan2
- MAGEB16 | c.-66-1604A>T | Intron (SNP) | VAF 30/183 reads (16%) | called by muse, mutect2, varscan2
- MAGEB16 | c.-66-1603G>T | Intron (SNP) | VAF 32/190 reads (17%) | called by muse, mutect2, varscan2
- MBP | c.682-21C>T | Intron (SNP) | VAF 12/127 reads (9%) | catalogued as rs374025717; called by muse, mutect2
- MPPED2 | c.*8G>A | 3'UTR (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- NR1D2 | c.1146+623G>T | Intron (SNP) | VAF 14/179 reads (8%) | called by muse, mutect2
- ORC5 | c.*7G>A | 3'UTR (SNP) | VAF 12/122 reads (10%) | catalogued as rs1336862840; called by muse, mutect2
- PCDH10 | c.*40C>T | 3'UTR (SNP) | VAF 17/202 reads (8%) | called by muse, mutect2
- PCTP | c.141+188C>A | Intron (SNP) | VAF 24/219 reads (11%) | called by muse, mutect2, varscan2
- PDE7B | c.83-70323C>T | Intron (SNP) | VAF 30/245 reads (12%) | catalogued as COSV57511069; called by muse, mutect2, varscan2
- PRDX2 | c.257+98C>T | Intron (SNP) | VAF 12/108 reads (11%) | catalogued as rs1353840106; called by muse, mutect2, varscan2
- PTGDS | c.115-102G>T | Intron (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- RBM24 | c.-28G>A | 5'UTR (SNP) | VAF 4/34 reads (12%) | catalogued as rs1222259080; called by muse, mutect2, varscan2
- RFPL4AL1 | chr19:55777643 G>A | 3'Flank (SNP) | VAF 16/157 reads (10%) | called by muse, mutect2, varscan2
- SLC26A3 | c.1515-43C>A | Intron (SNP) | VAF 25/222 reads (11%) | called by muse, mutect2, varscan2
- SLC26A7 | c.1935+255C>T | Intron (SNP) | VAF 16/163 reads (10%) | catalogued as COSV99404276; called by muse, mutect2, varscan2
- SMIM3 | c.-90C>T | 5'UTR (SNP) | VAF 22/355 reads (6%) | called by muse, mutect2
- SNORD116-17 | chr15:25088061 G>A | 3'Flank (SNP) | VAF 10/126 reads (8%) | catalogued as rs577627769; called by muse, mutect2
- TANGO2 | c.451+61G>T | Intron (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2, varscan2
- TMEM18 | c.-9C>G | 5'UTR (SNP) | VAF 28/246 reads (11%) | catalogued as rs780548036; called by muse, mutect2
- XPO5 | c.*61C>T | 3'UTR (SNP) | VAF 44/376 reads (12%) | catalogued as rs768121449, COSV54832538; called by muse, mutect2, varscan2
- ZEB2 | chr2:144519989 A>G | 5'Flank (SNP) | VAF 15/179 reads (8%) | called by muse, mutect2
- ZNF696 | c.65-295C>T | Intron (SNP) | VAF 16/185 reads (9%) | called by muse, mutect2
- ZNF720 | c.361+718G>T | Intron (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
